Somatic mutation profile of tumor specimen TCGA-62-8402-01A (aliquot TCGA-62-8402-01A-11D-2323-08) from TCGA case TCGA-62-8402, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.7 years (26,934 days).
Specimen TCGA-62-8402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa64d00a-b405-4526-a033-bd308fe79c5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-8402-10A (Blood Derived Normal), aliquot TCGA-62-8402-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b22cb1a6-e0f7-46b2-8067-e9117e5004d4

The open-access MAF lists 58 somatic variants for this specimen: 35 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 21, Nonsense Mutation 2, RNA 1, Nonstop Mutation 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 19/59 reads (32%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ABCA10 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 99/127 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179438451, COSV99288460; called by muse, mutect2, varscan2
- ABCB7 | c.643G>C p.G215R (on ENST00000373394 / NM_001271696.3; = p.G216R on NM_004299.6) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV99504249; called by muse, mutect2
- ANK2 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); catalogued as rs1400057725, COSV100001087; called by muse, mutect2, varscan2
- ATP8A2 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV99679740, COSV99681407; called by muse, mutect2, varscan2
- BAK1 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV62349465; called by muse, mutect2, varscan2
- BCKDK | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); catalogued as COSV99570582; called by muse, mutect2, varscan2
- CDH4 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100848697; called by muse, mutect2
- DNAH5 | c.3082G>C p.E1028Q | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV54218086, COSV99448639; called by muse, mutect2, varscan2
- DUS3L | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57833388; called by muse, varscan2
- EIF4E | c.143T>C p.F48S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99794748; called by muse, mutect2
- FAM104B | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100146042, COSV59778902; called by muse, mutect2
- FCRL2 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100829891; called by muse, mutect2, varscan2
- GCC2 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 77/98 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100565401, COSV59179625; called by muse, mutect2, varscan2
- GPBP1L1 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs765686043, COSV99322207; called by muse, mutect2, varscan2
- GSPT2 | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV100468106; called by muse, mutect2, varscan2
- HIPK2 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100702165; called by muse, mutect2
- KIAA0895L | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51783819, COSV99220479; called by muse, mutect2, varscan2
- KIT | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55389178, COSV55391725, COSV99855014; called by muse, mutect2, varscan2
- MAGEB1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100974933, COSV66776336; called by muse, mutect2, varscan2
- NFASC | c.2102G>A p.R701H (on ENST00000339876 / NM_001378329.1; = p.R697H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768041295, COSV100363580; called by muse, mutect2, varscan2
- OR8H2 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs779838445, COSV57943323; called by muse, mutect2, varscan2
- PCDHA1 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV100974346; called by muse, mutect2, varscan2
- PCNX2 | c.4762C>T p.L1588F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99267082; called by muse, mutect2, varscan2
- RYR2 | c.3877C>T p.Q1293* | Nonsense Mutation (SNP) | VAF 32/231 reads (14%) | catalogued as COSV100769623; called by muse, mutect2, varscan2
- SCARA5 | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV100107818, COSV57278545; called by muse, mutect2, varscan2
- SLC26A7 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV99403152; called by muse, mutect2, varscan2
- SNAP47 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100248084, COSV100248597; called by muse, mutect2, varscan2
- STK17B | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99826068; called by muse, mutect2, varscan2
- TENM1 | c.1277A>C p.H426P | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100949772; called by muse, mutect2, varscan2
- THAP12 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs1325164130, COSV99472897; called by muse, mutect2, varscan2
- TKTL1 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99473905; called by muse, mutect2, varscan2
- TP53 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs147002414, COSV52688422, COSV53250031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YIPF4 | c.735A>T p.*245Cext*12 | Nonstop Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99479842; called by muse, mutect2, varscan2
- POLR2A | c.5719C>T p.P1907S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC9 | c.2118A>G p.Q706= | Silent (SNP) | VAF 138/195 reads (71%) | catalogued as COSV99685426; called by muse, mutect2, varscan2
- AC244197.3 | c.651C>T p.H217= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as rs782163574, COSV100557946; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIS3L2 | c.1728C>G p.R576= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV56050408, COSV99806007; called by muse, mutect2, varscan2
- GLRA4 | c.303G>A p.Q101= | Silent (SNP) | VAF 26/241 reads (11%) | catalogued as COSV101009625; called by muse, mutect2, varscan2
- HOOK2 | c.1269C>T p.C423= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs778364046, COSV99317499; called by muse, mutect2, varscan2
- KATNIP | c.3960G>A p.E1320= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV55190382, COSV99850829; called by muse, mutect2, varscan2
- LILRB5 | c.270T>C p.Y90= | Silent (SNP) | VAF 131/231 reads (57%) | catalogued as COSV100300294; called by muse, mutect2, varscan2
- MAS1L | c.423C>A p.V141= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV101009676; called by muse, mutect2, varscan2
- MRPL45 | c.331C>A p.R111= | Silent (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- NEURL4 | c.2847G>A p.E949= | Silent (SNP) | VAF 47/68 reads (69%) | catalogued as rs1402693202, COSV100222886; called by muse, mutect2, varscan2
- NOL11 | c.792A>G p.A264= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as COSV99474996; called by muse, mutect2, varscan2
- OTOA | c.1887A>G p.R629= (on ENST00000286149; = p.R615= on NM_144672.4) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99624298; called by muse, mutect2, varscan2
- PCDHGB5 | c.1554C>T p.Y518= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- PCSK1N | c.234G>A p.A78= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99504813; called by muse, mutect2, varscan2
- PLCXD3 | c.486G>T p.L162= | Silent (SNP) | VAF 22/299 reads (7%) | catalogued as COSV100125606; called by muse, mutect2
- PPP5C | c.1101G>A p.R367= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99181756; called by muse, mutect2, varscan2
- PRAMEF20 | c.1191G>T p.L397= | Silent (SNP) | VAF 239/512 reads (47%) | called by muse, mutect2, varscan2
- SLC9A1 | c.1350C>T p.F450= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99849548; called by muse, mutect2, varscan2
- SMARCA4 | c.3756G>A p.E1252= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100758434; called by muse, mutect2, varscan2
- ZDHHC17 | c.654C>T p.N218= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV58354943; called by muse, mutect2
- ZSWIM5 | c.1641C>T p.D547= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs749017745, COSV100655514; called by muse, mutect2, varscan2
- CCNQP1 | n.14T>C | RNA (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- EIF4B | c.-2A>G | 5'UTR (SNP) | VAF 42/187 reads (22%) | catalogued as rs867881378, COSV50411541; called by muse, mutect2, varscan2
